Somatic mutation profile of tumor specimen MP2PRT-PAVSTK-TMP1-A (aliquot MP2PRT-PAVSTK-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVSTK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (995 days).
Specimen MP2PRT-PAVSTK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c899f8c-b766-420d-b5a1-0916ce960874.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVSTK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVSTK-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d94a8733-a0f1-44e8-9b7a-0c4b34bfd27d

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 9, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPZA3 | c.709C>G p.Q237E | Missense Mutation (SNP) | VAF 10/333 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.587); catalogued as COSV56848485; called by muse, mutect2
- CNNM2 | c.1798C>T p.R600W | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs749627094, COSV64001469; called by muse, mutect2, varscan2
- COL6A3 | c.3671C>T p.P1224L | Missense Mutation (SNP) | VAF 85/181 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs754323567, COSV55091071, COSV55110152; called by muse, mutect2, varscan2
- EFCAB5 | c.3921G>C p.K1307N | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV57928497; called by muse, mutect2
- FBXL7 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 42/325 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.238); catalogued as rs765845939; called by muse, mutect2, varscan2
- HPS3 | c.2250G>C p.K750N | Missense Mutation (SNP) | VAF 33/333 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs747197669; called by muse, mutect2
- MC1R | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 104/606 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as rs774680166, COSV59626514; called by muse, mutect2, varscan2
- PABPC5 | c.241T>G p.F81V | Missense Mutation (SNP) | VAF 45/438 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57042883; called by muse, mutect2, varscan2
- PVRIG | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 12/281 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV52782941; called by muse, mutect2
- ADAMTS20 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 83/305 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- C11orf16 | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 12/393 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.363); called by muse, mutect2
- CEP85L | c.2140C>T p.Q714* | Nonsense Mutation (SNP) | VAF 14/410 reads (3%) | called by muse, mutect2
- DCDC2B | c.919G>C p.D307H | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- KCNJ14 | c.778G>C p.D260H | Missense Mutation (SNP) | VAF 105/379 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRDN | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- TRIM56 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 54/629 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- TTC29 | c.97C>G p.Q33E | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBA2 | c.481T>G p.C161G | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- UBFD1 | c.723G>C p.W241C | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, varscan2
- ANKRD45 | c.513G>C p.L171= | Silent (SNP) | VAF 54/179 reads (30%) | catalogued as COSV60960572; called by muse, mutect2, varscan2
- C1orf210 | c.135G>A p.S45= | Silent (SNP) | VAF 50/427 reads (12%) | catalogued as rs749780582; called by muse, mutect2, varscan2
- DDX43 | c.105G>A p.L35= | Silent (SNP) | VAF 18/494 reads (4%) | catalogued as COSV100946485, COSV64836729; called by muse, mutect2
- FBXO34 | c.1374C>T p.I458= | Silent (SNP) | VAF 38/410 reads (9%) | catalogued as rs758392460, COSV58254239, COSV58255018; called by muse, mutect2
- IGSF3 | c.2914C>T p.L972= (on ENST00000369486 / NM_001007237.3; = p.L992= on NM_001542.4) | Silent (SNP) | VAF 59/314 reads (19%) | called by muse, varscan2
- KLHL26 | c.1833C>T p.A611= | Silent (SNP) | VAF 46/804 reads (6%) | catalogued as rs1205400344, COSV56318269; called by muse, mutect2
- NRG1 | c.1623C>T p.L541= (on ENST00000405005 / NM_013964.5; = p.L546= on NM_013956.5) | Silent (SNP) | VAF 115/389 reads (30%) | catalogued as rs543637798; called by muse, mutect2, varscan2
- PCDHA8 | c.2034G>A p.A678= | Silent (SNP) | VAF 33/422 reads (8%) | catalogued as COSV65326549; called by muse, mutect2
- TRO | c.333C>G p.V111= | Silent (SNP) | VAF 97/468 reads (21%) | called by muse, mutect2, varscan2
- ARHGEF11 | c.583-1681G>C | Intron (SNP) | VAF 88/296 reads (30%) | catalogued as COSV63815043; called by muse, mutect2, varscan2
